Somatic mutation profile of tumor specimen TCGA-F5-6811-01A (aliquot TCGA-F5-6811-01A-11D-1826-10) from TCGA case TCGA-F5-6811, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIA; Age at diagnosis: 72.8 years (26,575 days).
Specimen TCGA-F5-6811-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9af2f9ea-2a3c-48ac-aca1-2dcb73274038.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6811-10A (Blood Derived Normal), aliquot TCGA-F5-6811-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d6aaae-c17a-4e08-854a-65732f8b88b7

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 24, Nonsense Mutation 2, Frame Shift Ins 2, RNA 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 34/49 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCC1 | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs545772203, COSV60686964; called by muse, mutect2, varscan2
- ADAMTS12 | c.4587G>T p.Q1529H | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100710438; called by muse, mutect2, varscan2
- ADGRG2 | c.872A>C p.N291T (on ENST00000379869 / NM_001079858.3; = p.N288T on NM_005756.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV100491997; called by muse, mutect2, varscan2
- ALAS1 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 102/232 reads (44%) | catalogued as COSV100050238; called by muse, mutect2, varscan2
- APLN | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as rs377120516, COSV100278248; called by muse, mutect2, varscan2
- C17orf64 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1417608936, COSV52257726; called by muse, mutect2, varscan2
- C4BPA | c.1369G>A p.G457S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs867765131, COSV100891167; called by muse, mutect2, varscan2
- CAMKK2 | c.796+2T>C p.X266_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV61213114; called by muse, mutect2, varscan2
- CCT7 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.672); catalogued as COSV99240587; called by muse, mutect2, varscan2
- CHRD | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs745397410, COSV52610924; called by muse, mutect2, varscan2
- CLPX | c.1010C>A p.A337E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100269343; called by muse, mutect2, varscan2
- CPT1C | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs763153595, COSV99773298; called by muse, mutect2, varscan2
- CSDC2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs373284212, COSV99348055; called by muse, varscan2
- DMD | c.3007G>A p.V1003M | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs746416489, COSV63759117; called by muse, mutect2, varscan2
- DST | c.1465A>G p.I489V (on ENST00000361203 / NM_001374722.1; = p.I163V on NM_001723.6) | Missense Mutation (SNP) | VAF 102/242 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55018135; called by muse, mutect2, varscan2
- FAM184A | c.159G>A p.K53= | Splice Region (SNP) | VAF 11/24 reads (46%) | catalogued as COSV58854883; called by muse, mutect2, varscan2
- FARP1 | c.121T>C p.S41P | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.37); PolyPhen benign (0.174); catalogued as COSV60329528; called by muse, mutect2, varscan2
- FAT3 | c.5890A>G p.S1964G | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV53119090; called by muse, mutect2, varscan2
- FAT4 | c.6022C>T p.R2008W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58671195; called by muse, mutect2, varscan2
- FBXO15 | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs144253482, COSV54044307; called by muse, mutect2, varscan2
- GABRA5 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as COSV59480384; called by muse, mutect2, varscan2
- GCK | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1306714325, CM1212981, COSV99789933; called by muse, mutect2, varscan2
- IGLV3-21 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs761373011; called by muse, mutect2, varscan2
- KCND2 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 196/326 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100474268; called by muse, mutect2, varscan2
- KCNH4 | c.2160G>T p.K720N | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV52918181; called by muse, mutect2, varscan2
- KLHL24 | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.274); catalogued as rs758623370, COSV54424631; called by muse, mutect2, varscan2
- MARCO | c.1307A>G p.E436G | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503269; called by muse, mutect2, varscan2
- MEPCE | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs750586930, COSV52769290; called by muse, mutect2, varscan2
- MIOS | c.2534A>T p.D845V | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV60768741; called by muse, varscan2
- MNDA | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as rs773707693, COSV100933266; called by muse, mutect2, varscan2
- MPDZ | c.1392G>T p.M464I | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV59943483; called by muse, mutect2, varscan2
- MRPS24 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV58182342; called by muse, mutect2, varscan2
- MTNR1B | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV57068635; called by muse, mutect2, varscan2
- MYH14 | c.3175C>T p.R1059C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs1158319494, COSV99222108; called by muse, mutect2, varscan2
- NEU4 | c.595G>A p.A199T (on ENST00000391969 / NM_001167602.3; = p.A211T on NM_080741.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as rs377551488; called by muse, mutect2, varscan2
- OR2A25 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs757511266, COSV68717707; called by muse, mutect2, varscan2
- OR2G2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.047); catalogued as rs145391203, COSV60739860; called by muse, mutect2, varscan2
- OR2L13 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs202188433, COSV63549839; called by muse, mutect2, varscan2
- OR2T33 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58815643; called by muse, mutect2, varscan2
- OR56A1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs139301829; called by muse, mutect2, varscan2
- OTOP3 | c.1690C>T p.R564C | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778665286, COSV60912786; called by muse, mutect2, varscan2
- PAPLN | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV99389292; called by muse, mutect2, varscan2
- PCDHB7 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as rs782364415, COSV50762092; called by muse, mutect2, varscan2
- PIGR | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.345); catalogued as COSV100732460; called by muse, mutect2, varscan2
- PKHD1 | c.10490C>A p.A3497D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100943925; called by muse, mutect2, varscan2
- POLL | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs548269958, COSV54575579; called by muse, mutect2, varscan2
- PRKCZ | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.137); catalogued as rs745674432, COSV101057565, COSV66067938; called by muse, mutect2, varscan2
- RGCC | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as rs1475555861, COSV101036967; called by muse, mutect2, varscan2
- SCFD1 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as rs1184017355; called by muse, mutect2
- SCN2A | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51843248; called by muse, mutect2, varscan2
- SCYL2 | c.984T>G p.D328E | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV62569051; called by muse, mutect2
- SFTPB | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs201986026; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIM1 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs137870558, CM139287; called by muse, mutect2, varscan2
- SPHKAP | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.073); catalogued as COSV60881311; called by muse, mutect2, varscan2
- STAB2 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs374968745; called by muse, mutect2, varscan2
- SYT16 | c.1423A>G p.S475G | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV101413528; called by muse, mutect2, varscan2
- TBC1D32 | c.776A>G p.Y259C | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1324379304, COSV99249741; called by muse, varscan2
- TENM1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.013); catalogued as rs146613496, COSV100950255, COSV64446948; called by muse, mutect2, varscan2
- TRPC1 | c.2315G>A p.R772Q (on ENST00000476941 / NM_001251845.2; = p.R738Q on NM_003304.4) | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs982977298, COSV56423815; called by muse, mutect2, varscan2
- TTLL7 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99552028; called by muse, mutect2, varscan2
- USP28 | c.2044C>T p.Q682* | Nonsense Mutation (SNP) | VAF 77/210 reads (37%) | catalogued as COSV50208915; called by muse, mutect2, varscan2
- VGLL3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.122); catalogued as rs1335449303, COSV67352631; called by muse, mutect2, varscan2
- ZNF536 | c.3053T>C p.L1018P | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100834860; called by muse, mutect2
- APC | c.3969dup p.P1324Sfs*8 | Frame Shift Ins (INS) | VAF 81/154 reads (53%) | called by mutect2, pindel, varscan2
- CENPL | c.714del p.E238Dfs*67 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | called by mutect2, pindel, varscan2
- MRC1 | c.1904C>A p.P635Q | Missense Mutation (SNP) | VAF 262/541 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLN | c.592dup p.C198Lfs*2 | Frame Shift Ins (INS) | VAF 51/138 reads (37%) | called by mutect2, pindel, varscan2
- ALG3 | c.531G>A p.V177= | Silent (SNP) | VAF 66/197 reads (34%) | catalogued as COSV99890906; called by muse, mutect2, varscan2
- AP002512.3 | c.48G>A p.T16= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs770674616, COSV100392370; called by muse, mutect2, varscan2
- APBB2 | c.1515C>T p.R505= (on ENST00000295974 / NM_001166050.2; = p.R506= on NM_004307.2) | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as rs377258984; called by muse, mutect2, varscan2
- CCDC114 | c.1980G>A p.P660= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs572589870, COSV100196484; ClinVar: likely benign; called by muse, mutect2
- CDH1 | c.318C>T p.T106= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs786201857, COSV55733721; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH4 | c.2049C>T p.A683= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs201703403, COSV64644716; called by muse, mutect2
- ERBIN | c.114G>A p.P38= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs766345241, COSV99396180; called by muse, mutect2, varscan2
- EVX2 | c.153G>A p.P51= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV57963658; called by muse, mutect2, varscan2
- MAP2K7 | c.381C>G p.G127= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV101208999; called by muse, mutect2, varscan2
- MOV10L1 | c.1443C>T p.T481= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs1026603538, COSV99433058; called by muse, mutect2, varscan2
- PAPPA2 | c.1887C>T p.H629= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as rs759601604, COSV62779278; called by muse, mutect2, varscan2
- PCDHA5 | c.1611C>T p.R537= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV65351753; called by muse, mutect2, varscan2
- PCDHGA5 | c.186C>T p.R62= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as rs1182506562, COSV53960394; called by muse, mutect2, varscan2
- PPCS | c.366G>A p.E122= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs769564760, COSV65333681; called by muse, mutect2, varscan2
- SARS1 | c.1422G>A p.A474= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as rs374920184; called by muse, mutect2, varscan2
- SH3RF3 | c.2592C>G p.T864= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100512485; called by muse, mutect2, varscan2
- SLC30A9 | c.24C>T p.A8= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV100048017; called by muse, mutect2, varscan2
- TGFB2 | c.555C>T p.I185= | Silent (SNP) | VAF 32/131 reads (24%) | catalogued as rs760740958, COSV65110000; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMCC2 | c.1188C>T p.S396= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs558212864, COSV100319203; called by muse, mutect2, varscan2
- TMEM131L | c.3477G>A p.V1159= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs765576447, COSV99546999; called by muse, mutect2, varscan2
- TMEM202 | c.174G>A p.T58= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs148667101; called by muse, mutect2, varscan2
- TOP3B | c.2301C>T p.S767= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs1245710958, COSV99601332; called by muse, mutect2, varscan2
- UNC13C | c.3489G>A p.K1163= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV52879306; called by muse, mutect2, varscan2
- ZDHHC8 | c.2205C>T p.T735= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs757217788, COSV57710766; called by muse, mutect2, varscan2
- MIR891A | n.71G>T | RNA (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- ZNF833P | n.819T>G | RNA (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
